MMRF case MMRF_2438 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/ad1da7b1-673c-494a-9752-4f01ffc6a4b6

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 51 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 51.6 years (18,846 days); ISS stage: I; Days to last known disease status: 723 days (2.0 years); Days to last follow up: 723 days (2.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 106 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 152 days; Days to treatment end: 152 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 288 days; Days to treatment end: 457 days (1.3 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 458 days (1.3 years); Days to treatment end: 606 days (1.7 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 458 days (1.3 years); Days to treatment end: 465 days (1.3 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 656 days (1.8 years); Days to treatment end: 671 days (1.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone + Doxorubicin + Other; Regimen or line of therapy: Third line of therapy; Days to treatment start: 684 days (1.9 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 723.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -51 (ECOG 1): M Protein 4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 29.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 23 g/L; Immunoglobulin A 0.67 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 2.24 µg/mL; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 5.26 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.21 mmol/L; Calcium 2.4 mmol/L; Albumin 45 g/L; Total Protein 8.7 g/dL; Glucose 5.5 mmol/L.
- Day 53 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.158 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.16 mg/dL; Immunoglobulin G 8.78 g/L; Immunoglobulin A 0.35 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 3.68 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 6.33 ×10⁹/L; Platelets 81 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.85 mmol/L; Calcium 2.15 mmol/L; Albumin 45 g/L; Total Protein 6.9 g/dL.
- Day 129: M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.825 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.633 mg/dL; Immunoglobulin G 4.94 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 1.48 µg/mL; Lactate Dehydrogenase 3.42 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 28.6 ×10⁹/L; Absolute Neutrophil 23.7 ×10⁹/L; Platelets 104 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 45 g/L; Total Protein 6.6 g/dL; Glucose 7.59 mmol/L.
- Day 233 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.0327 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.139 mg/dL; Immunoglobulin G 4.46 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.08 g/L; Lactate Dehydrogenase 3.72 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.74 ×10⁹/L; Platelets 91 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.64 mmol/L; Calcium 2.28 mmol/L; Albumin 45 g/L; Total Protein 6.2 g/dL.
- Day 268 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.261 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.687 mg/dL; Immunoglobulin G 4.19 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 3.27 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 5.94 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 49 g/L; Total Protein 6.7 g/dL.
- Day 382 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.934 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.24 mg/dL; Immunoglobulin G 6.14 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 4.02 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 114 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 4.68 mmol/L; Calcium 2.23 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL.
- Day 494: Hemoglobin 5.7 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.86 ×10⁹/L; Platelets 68 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 4.57 mmol/L; Calcium 2.15 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL.
- Day 571 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.821 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.726 mg/dL; Immunoglobulin G 5.29 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 3.1 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.44 ×10⁹/L; Platelets 118 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 5.39 mmol/L; Calcium 2.35 mmol/L; Albumin 46 g/L; Total Protein 6.5 g/dL.
- Day 676 (ECOG 1): M Protein 1.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.168 mg/dL; Immunoglobulin G 16.4 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.07 g/L; Hemoglobin 5.27 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.73 ×10⁹/L; Platelets 117 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.11 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 7.2 g/dL; Glucose 6.66 mmol/L.

Other clinical attributes
- Day -51: Weight: 86 kg; Height: 159 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2438_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -51 days.
- Sample MMRF_2438_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -51 days.
